Surgical pathology report (de-identified scan), TCGA case TCGA-06-5418, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-5418-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Surgical Pathology Report

TCCA 06-5418

[REDACTED]

CLINICAL HISTORY

[REDACTED] experienced dysphasia, and on MRI has a ring-enhancing right frontal lesion close to Broca's area.

OPERATIVE DIAGNOSES

Glioblastoma

Operation/Specimen: A: Brain, left frontal tumor, resection

B: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, left frontal, excision:

1. Glioblastoma.

2. MIB-1 proliferation index: 40%.

See Microscopy Description and Comment.

COMMENT

Sections contain portions of portions of brain that are infiltrated and extensively effaced by a cellular astrocytic neoplastic proliferation that has nuclear anaplasia, brisk mitotic activity, focal microvascular cellular proliferation, and extensive areas of tumor necrosis, the smaller ones with pseudopalisading. The neoplastic cells tend to be small and have round/ovoid nuclei. The MIB-1 proliferation index is high at about 40%.

The findings are those of a small cell glioblastoma, WHO IV/IV. Results of molecular testing will appear in addendum reports.

[REDACTED]

INTRA-OPERATIVE CONSULTATION

A.

Brain, left frontal tumor, resection: Glial neoplasm, high histological grade

(C/W glioblastoma).

[REDACTED] Touch preparation smears performed at

[REDACTED] and results reported to the Physician of Record.

[page 2 of 2]
[REDACTED]

GROSS DESCRIPTION

A.

"Left frontal brain tumor," received fresh, two fragments, 1.7 cm across in aggregate. Semi firm, greyish/white. In total, A1.

B.

Brain, excision biopsy: CONTAINER LABEL: patient's name

FIXATIVE: fresh

GENERAL: Received are few tan-pink to red fragments, aggregating to 2.4 x 1 x

0.3 cm.

SECTIONS: 1, [REDACTED]

[REDACTED]

[REDACTED]

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates dense gliofibrillary background within the neoplasm. The CD34 depicts a small vessel vascular network with

focal microvascular cellular proliferation. With the MIB-1 there is a proliferation index of about 40% in many areas of the tumor.

ICD-9(s):

191.1 191.1

[REDACTED]

Histo Data

Part A: Brain, left frontal tumor, resection

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
FS H/E x 1		1	[REDACTED]	
H/E x 1		1	[REDACTED]	

Part B: Brain, excision biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
CD34-DA x 1		1	[REDACTED]	
EGFR-slides x 1		1	[REDACTED]	larger fragment @
top.				
Thanks				
mGFAP-DA x 1		1	[REDACTED]	
H/E x 1		1	[REDACTED]	
MGMT-curls x 1		1	[REDACTED]	
MIB1-DA x 1		1	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file d5831ffc-578b-4b5b-ad79-521b8acb18b4 (TCGA-06-5418.84947803-ECC1-44F4-B158-EC517A23AD43.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).